Surgical pathology report (de-identified scan), TCGA case TCGA-86-8279, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8279-01A (Primary Tumor).

[page 1 of 3]
TCGA Pathology Reports

ID	Gross Description	Microscopic Description	Diagnosis Details	Comments

[page 2 of 3]
Formatted Path Report

LUNG TISSUE CHECKLIST

Specimen type: Excision of tumor
Tumor site: Lung
Tumor size: 3 x 3 x 3 cm
Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Tumor extent: Visceral pleura
Other tumor nodules: Not specified
Lymph nodes: 1/1 positive for metastasis (Intrathoracical 1/1)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Margins: Not specified
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: Positive for CD15, CK7, TTF1, CEA; negative for CK20, CDX2

OpenC
lica ID

Excision date

[page 3 of 3]
Lateralit
y

Right-
upper

Source: NCI Genomic Data Commons file ffea7548-11fb-4286-b3e4-93754acf3d02 (TCGA-86-8279.E7E4B4FD-F47D-4AAB-826C-0EF1F620A739.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).